National Lung Screening Trial (NLST) participant 207869 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 35 effective mAs, display field of view 39 cm, reconstruction filter Siemens, other.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Abnormalities recorded by the reading radiologist on the CT screens (1 abnormality; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the lingula; longest diameter 13 mm, longest perpendicular diameter 12 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 73.

Lung cancer (2 primary lung cancer records; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 169, study year T0. Site: upper lobe of lung (ICD-O-3 C34.1), determined from cytology. Primary tumour location: left upper lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Tumour size on pathology: 13 mm. AJCC 6th edition staging: stage IA (best stage, from clinical TNM); clinical T1 N0 M0 (stage IA); pathologic TX NX MX. AJCC 7th edition staging: stage IA; clinical T1a N0 M0; pathologic TX NX MX. Summary stage: localized.
2. Subsequent primary lung cancer, diagnosed day 1,130, study year T3. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Histology: bronchiolo-alveolar adenocarcinoma, NOS (ICD-O-3 8250/3). Grade: moderately differentiated (G2). Tumour size on pathology: 7 mm. AJCC 6th edition staging: stage IA (best stage, from pathologic TNM); clinical T1 NX MX; pathologic T1 N0 M0 (stage IA). Summary stage: localized.

Follow-up
Last known free of lung cancer: day 169 (for ACRIN participants with lung cancer this field holds the diagnosis date).
